Somatic mutation profile of tumor specimen TARGET-10-PAPDMU-09A (aliquot TARGET-10-PAPDMU-09A-01D) from TARGET case TARGET-10-PAPDMU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,132 days).
Specimen TARGET-10-PAPDMU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ab03b88-40d6-43fb-934e-fc022e9e9dea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDMU-10A (Blood Derived Normal), aliquot TARGET-10-PAPDMU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfd1ec6c-8759-4505-949c-d3528979a250

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CORIN | c.2440C>G p.P814A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903866; called by muse, mutect2, varscan2
- FBXO46 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs374509869; called by muse, mutect2, varscan2
- FLG | c.9958C>T p.R3320C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770664817, COSV64239791; called by muse, mutect2, varscan2
- MIDN | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs1299332312; called by muse, mutect2, varscan2
- UGT2B7 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1392179428, COSV100535219; called by muse, mutect2, varscan2
- WT1 | c.1300dup p.T434Nfs*9 | Frame Shift Ins (INS) | VAF 12/92 reads (13%) | catalogued as COSV60082220; called by mutect2, pindel, varscan2
- ZNF335 | c.2662C>G p.P888A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs748584505; called by muse, mutect2, varscan2
- AP002495.1 | c.539G>T p.R180L (on ENST00000528511; = p.R111L on NM_001375848.1) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- GFY | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGA9 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- PAX5 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTF1 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TDRD5 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2
- ZNF778 | c.571T>C p.C191R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FBXO27 | c.630C>T p.D210= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs552069426, COSV53072729; called by muse, mutect2, varscan2
- PRKCZ | c.1068C>T p.Y356= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs200407187, COSV99059614; called by muse, mutect2, varscan2
- PSD2 | c.1086C>T p.D362= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs747518596, COSV51199034; called by muse, mutect2, varscan2
- CTU2 | c.69-94A>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- SCOC | c.181+486G>A | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
